Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4IU, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4IU-01A (Primary Tumor).

[page 1 of 2]
Gross Description: In pylorus-lesser curvature, there is an ulcer with 4x5x1.5cm in size, firm and myxoid gray surface. Surrounding mucosa is unfold.

Microscopic Description: Mucosa is ulcerated. The tumor is composed of signet-ring cell has a large mucin vacuole that fills the cytoplasm and displaces the nucleus floating in pools of extracellular mucin. Tumor intervenes in muscle bundles and is invasion in serosa. Nuclei are hyperchromatic and irregular enlarged with prominent nucleoli. Mitoses are present. Stroma is invasion of inflammatory cells.

Diagnosis Details: Adenocarcinoma, diffuse type, infiltrating serosa.

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy

Tumor site: Antrum

Tumor size: 5 x 4 x 1.5 cm

Tumor features: Ulcerated

Histologic type: Adenocarcinoma, diffuse type

Histologic grade: Poorly differentiated

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: 1/6 positive for metastasis (Regional 1/6)

Lymphatic invasion: Present

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

QCF: adenocarcinoma, NOS 8140/3
path: adenocarcinoma, diffuse type 8145/3
Site: stomach, antrum C16.3

hw
10/2/12

tss submitted dx discrepancy
form to reflect dx as
adenocarcinoma, NOS -BCR

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name) _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Intestinal-Adenocarcinoma Tubular type	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Stomach-adenocarcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.		Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 9870fda2-085f-4f8d-a5ff-35e652434a2c (TCGA-BR-A4IU.9FF6D7F5-1C75-45E5-AC2F-BDFC30272D03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).